Somatic mutation profile of tumor specimen MMRF_2444_1_BM_CD138pos (aliquot MMRF_2444_1_BM_CD138pos_T1_KHS5U_L11252) from MMRF case MMRF_2444, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 81.2 years (29,644 days).
Specimen MMRF_2444_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4af6862d-9c21-4f12-9961-8bb5ffca8251.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2444_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2444_1_PB_WBC_C3_KHS5U_L11251; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4bdf6666-708f-4bed-ac88-b3136889f02e

The open-access MAF lists 113 somatic variants for this specimen: 46 protein-altering or splice-affecting, 14 silent, 53 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, 3'UTR 28, Silent 14, Intron 14, 5'UTR 4, Nonsense Mutation 3, 5'Flank 3, 3'Flank 3, Splice Site 2, Frame Shift Ins 2, Frame Shift Del 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRB1 | c.3172G>T p.E1058* | Nonsense Mutation (SNP) | VAF 81/200 reads (41%) | catalogued as rs564754426, COSV66328611; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 55/619 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs121434595, COSV54736386, COSV54736476, COSV54736550; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ABCA13 | c.13543G>A p.V4515I | Missense Mutation (SNP) | VAF 96/283 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as rs767565751, COSV101291288, COSV68942905; called by muse, mutect2, varscan2
- ASPSCR1 | c.809C>T p.P270L | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as rs759294150, COSV60729053; called by mutect2, varscan2
- BRSK2 | c.1162G>A p.V388M | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.557); catalogued as rs374367074; called by muse, mutect2, varscan2
- BUB1B | c.1396G>A p.D466N | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.331); catalogued as rs1332535867; called by muse, mutect2, varscan2
- CPSF4 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 51/122 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs755235208, COSV52856414, COSV52859874; called by muse, mutect2, varscan2
- DIS3 | c.1591T>G p.Y531D | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100899975, COSV66706617; called by muse, mutect2, varscan2
- IGLL5 | c.22G>A p.V8M | Missense Mutation (SNP) | VAF 38/59 reads (64%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.157); catalogued as rs571799774; called by muse, mutect2, varscan2
- KRT5 | c.1630G>T p.G544C | Missense Mutation (SNP) | VAF 64/141 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.38); catalogued as COSV52859051; called by muse, mutect2, varscan2
- NDST3 | c.510G>C p.K170N | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754098203, COSV99630252; called by muse, mutect2, varscan2
- PLSCR1 | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV61012585; called by muse, mutect2, varscan2
- PTPRK | c.2030del p.G677Efs*38 | Frame Shift Del (DEL) | VAF 79/237 reads (33%) | catalogued as COSV63890368; called by mutect2, pindel, varscan2
- TUBAL3 | c.562G>A p.V188M | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.901); catalogued as rs782012870, COSV66814175; called by muse, mutect2, varscan2
- TUBB4A | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 14/240 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.849); catalogued as rs1472127260, COSV51164408; called by muse, mutect2
- WHAMM | c.2029C>T p.R677W | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs746026792, COSV54500177; called by muse, mutect2
- ACSM6 | c.1334G>A p.G445D | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.565); called by muse, mutect2, varscan2
- AGRN | c.475A>G p.T159A | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- AHNAK2 | c.7433C>G p.T2478S | Missense Mutation (SNP) | VAF 78/211 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CAMSAP3 | c.334G>C p.G112R | Missense Mutation (SNP) | VAF 97/216 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CRTAC1 | c.474A>T p.E158D | Missense Mutation (SNP) | VAF 121/307 reads (39%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- CSPG4 | c.6389C>A p.P2130Q | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.246); called by muse, mutect2
- CSPG4 | c.6388C>A p.P2130T | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.013); called by muse, mutect2
- DIPK1C | c.218G>A p.G73D | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- DNAH10 | c.5968G>A p.G1990S (on ENST00000409039; = p.G1929S on NM_207437.3) | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- DYNC2H1 | c.8534dup p.N2845Kfs*4 | Frame Shift Ins (INS) | VAF 16/35 reads (46%) | called by mutect2, varscan2
- ERN1 | c.2654-8_2676del p.X885_splice | Splice Site (DEL) | VAF 12/62 reads (19%) | called by mutect2, pindel
- ESRRB | c.1299del p.G434Afs*96 | Frame Shift Del (DEL) | VAF 37/82 reads (45%) | called by mutect2, pindel, varscan2
- EVPL | c.1996G>A p.G666R | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GATA2 | c.290G>A p.W97* | Nonsense Mutation (SNP) | VAF 15/36 reads (42%) | called by muse, mutect2, varscan2
- HHIPL1 | c.2024T>G p.L675R | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); called by muse, varscan2
- MCF2 | c.759A>C p.Q253H | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.97); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MISP3 | c.976C>T p.P326S (on ENST00000269720; = p.P184S on NM_001291291.2) | Missense Mutation (SNP) | VAF 54/136 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MRPS10 | c.297_300dup p.E101* | Nonsense Mutation (INS) | VAF 38/109 reads (35%) | called by mutect2, pindel, varscan2
- MSLNL | c.1628C>T p.P543L | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR56A5 | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- PLA2G4F | c.1452G>T p.E484D | Missense Mutation (SNP) | VAF 72/154 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- PPP2R3A | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- RTN2 | c.934C>T p.P312S | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.725); called by muse, varscan2
- RTN2 | c.829T>C p.W277R | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, varscan2
- SLITRK6 | c.1785T>G p.D595E | Missense Mutation (SNP) | VAF 74/112 reads (66%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SP9 | c.296C>G p.S99C | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SUSD4 | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- TDRD15 | c.4658dup p.L1553Ffs*24 | Frame Shift Ins (INS) | VAF 6/59 reads (10%) | called by mutect2, varscan2
- UBAP2L | c.1214-5_1217del p.X405_splice | Splice Site (DEL) | VAF 17/59 reads (29%) | called by mutect2, pindel, varscan2
- ZNF200 | c.147C>A p.H49Q | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ATXN3 | c.1014C>A p.I338= | Silent (SNP) | VAF 119/235 reads (51%) | called by muse, mutect2, varscan2
- EPB41L5 | c.1692T>C p.S564= | Silent (SNP) | VAF 70/162 reads (43%) | called by muse, mutect2, varscan2
- GATA6 | c.1758G>A p.P586= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs1315239737, COSV99333137; called by muse, mutect2, varscan2
- IGHV2-5 | c.96A>G p.K32= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as rs552815908; called by muse, mutect2
- IGLV1-44 | c.252C>G p.G84= | Silent (SNP) | VAF 42/161 reads (26%) | called by muse, varscan2
- KANSL1L | c.1122C>T p.D374= | Silent (SNP) | VAF 41/136 reads (30%) | called by muse, mutect2, varscan2
- LPAR1 | c.838C>T p.L280= | Silent (SNP) | VAF 38/122 reads (31%) | called by muse, mutect2, varscan2
- NTSR2 | c.222C>T p.S74= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs747359813; called by muse, mutect2, varscan2
- PCDHA12 | c.1575C>T p.H525= | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as rs372059660; called by muse, mutect2
- SHROOM3 | c.2733C>T p.P911= | Silent (SNP) | VAF 15/56 reads (27%) | called by muse, mutect2, varscan2
- SMARCD3 | c.33G>C p.V11= | Silent (SNP) | VAF 24/72 reads (33%) | called by muse, mutect2, varscan2
- SREBF2 | c.2391G>A p.A797= | Silent (SNP) | VAF 42/125 reads (34%) | catalogued as rs1197457902, COSV100761435; called by muse, mutect2, varscan2
- TMEM151A | c.276C>T p.S92= | Silent (SNP) | VAF 37/91 reads (41%) | catalogued as rs771810396; called by muse, mutect2, varscan2
- ZNF585A | c.2004G>A p.G668= (on ENST00000292841 / NM_001288800.2; = p.G613= on NM_152655.3) | Silent (SNP) | VAF 23/226 reads (10%) | catalogued as rs1461834076; called by muse, mutect2, varscan2
- ACOT9 | chrX:23702941 C>T | 3'Flank (SNP) | VAF 25/36 reads (69%) | called by muse, mutect2, varscan2
- ACOX3 | c.*174C>T | 3'UTR (SNP) | VAF 28/47 reads (60%) | called by muse, mutect2, varscan2
- AP006621.6 | c.*805G>A | 3'UTR (SNP) | VAF 16/42 reads (38%) | called by muse, mutect2, varscan2
- APOLD1 | c.*3016G>C | 3'UTR (SNP) | VAF 14/117 reads (12%) | called by muse, mutect2, varscan2
- ARMC8 | c.1134+354T>C | Intron (SNP) | VAF 16/53 reads (30%) | catalogued as rs1050440716; called by muse, mutect2, varscan2
- ATP5PB | c.*1339G>A | 3'UTR (SNP) | VAF 27/56 reads (48%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021208 G>C | 5'Flank (SNP) | VAF 63/161 reads (39%) | called by muse, mutect2, varscan2
- CBX8 | c.*850C>T | 3'UTR (SNP) | VAF 43/106 reads (41%) | called by muse, mutect2, varscan2
- CPEB3 | c.*3498T>C | 3'UTR (SNP) | VAF 23/91 reads (25%) | called by muse, mutect2, varscan2
- CTTNBP2NL | c.*1135G>T | 3'UTR (SNP) | VAF 17/77 reads (22%) | called by muse, mutect2, varscan2
- ELOVL4 | c.*193T>C | 3'UTR (SNP) | VAF 12/38 reads (32%) | called by muse, mutect2, varscan2
- FGFR3 | chr4:1807258 del CGTGAAGGGCCACTGGTCCCC | 3'UTR (DEL) | VAF 11/84 reads (13%) | called by mutect2, pindel, varscan2
- FLRT2 | c.*2343C>T | 3'UTR (SNP) | VAF 15/32 reads (47%) | called by muse, mutect2, varscan2
- FOXL1 | c.*716T>C | 3'UTR (SNP) | VAF 16/40 reads (40%) | catalogued as rs542697107; called by muse, mutect2, varscan2
- HGF | c.482+304G>T | Intron (SNP) | VAF 15/38 reads (39%) | called by muse, mutect2, varscan2
- HOXC5 | c.*654A>T | 3'UTR (SNP) | VAF 103/328 reads (31%) | called by muse, mutect2, varscan2
- IGLV1-41 | n.140G>A | RNA (SNP) | VAF 24/76 reads (32%) | catalogued as rs182902632; called by muse, mutect2, varscan2
- ITGA2 | c.*3487A>T | 3'UTR (SNP) | VAF 16/52 reads (31%) | called by muse, mutect2, varscan2
- ITGA6 | chr2:172427740 C>T | 5'Flank (SNP) | VAF 20/49 reads (41%) | called by muse, mutect2, varscan2
- ITIH1 | c.1925-94G>A | Intron (SNP) | VAF 97/281 reads (35%) | called by muse, mutect2, varscan2
- LEKR1 | c.*36G>A | 3'UTR (SNP) | VAF 11/27 reads (41%) | catalogued as rs1312091492; called by muse, mutect2, varscan2
- LRATD1 | c.*3891C>G | 3'UTR (SNP) | VAF 25/71 reads (35%) | called by muse, mutect2, varscan2
- LRRC36 | c.1494+35C>A | Intron (SNP) | VAF 46/111 reads (41%) | called by muse, mutect2, varscan2
- MAT1A | c.*797G>T | 3'UTR (SNP) | VAF 13/54 reads (24%) | called by muse, mutect2, varscan2
- MBP | c.139+200T>C | Intron (SNP) | VAF 4/11 reads (36%) | called by muse, mutect2, varscan2
- MCL1 | c.*2008A>G | 3'UTR (SNP) | VAF 25/93 reads (27%) | called by muse, mutect2, varscan2
- MIR9-2 | chr5:88670934 T>A | 5'Flank (SNP) | VAF 12/38 reads (32%) | called by mutect2, varscan2
- MITD1 | c.-32C>G | 5'UTR (SNP) | VAF 34/89 reads (38%) | called by muse, mutect2, varscan2
- MYG1 | c.217-40G>A | Intron (SNP) | VAF 11/51 reads (22%) | called by muse, mutect2, varscan2
- NOL4L | c.*2531C>T | 3'UTR (SNP) | VAF 40/83 reads (48%) | called by muse, mutect2, varscan2
- NRXN1 | c.1320+122A>G | Intron (SNP) | VAF 12/32 reads (38%) | catalogued as rs138719770; called by muse, varscan2
- ORAI2 | c.*4638G>A | 3'UTR (SNP) | VAF 48/167 reads (29%) | called by muse, mutect2, varscan2
- PAM | c.*23_*26del | 3'UTR (DEL) | VAF 155/481 reads (32%) | catalogued as rs1293875364; called by mutect2, pindel, varscan2
- PEAK1 | c.*3981G>T | 3'UTR (SNP) | VAF 7/25 reads (28%) | catalogued as rs1443115097; called by muse, mutect2, varscan2
- PIM1 | c.-293T>C | 5'UTR (SNP) | VAF 12/31 reads (39%) | called by muse, mutect2, varscan2
- PPDPFL | chr8:49075996 A>G | 3'Flank (SNP) | VAF 35/117 reads (30%) | catalogued as rs1309195558; called by muse, mutect2, varscan2
- PTGR1 | c.651+1092C>T | Intron (SNP) | VAF 12/31 reads (39%) | catalogued as rs889178397; called by muse, mutect2, varscan2
- RBMS3 | c.1307+134G>A | Intron (SNP) | VAF 35/95 reads (37%) | called by muse, mutect2, varscan2
- RNF32 | c.684+772G>A | Intron (SNP) | VAF 9/44 reads (20%) | called by muse, mutect2, varscan2
- RPL4 | c.*416del | 3'UTR (DEL) | VAF 18/52 reads (35%) | catalogued as rs922339500; called by mutect2, pindel, varscan2
- RPS6KB1 | c.*3076T>C | 3'UTR (SNP) | VAF 6/13 reads (46%) | called by muse, mutect2, varscan2
- RRP15 | c.*174T>C | 3'UTR (SNP) | VAF 5/48 reads (10%) | called by muse, mutect2, varscan2
- S1PR2 | c.-43+790G>T | Intron (SNP) | VAF 21/70 reads (30%) | called by muse, mutect2
- SCARB2 | c.*703G>T | 3'UTR (SNP) | VAF 23/68 reads (34%) | called by muse, mutect2, varscan2
- SKIV2L | c.3541-46C>G | Intron (SNP) | VAF 146/400 reads (37%) | called by muse, mutect2, varscan2
- SLC26A7 | c.*2994A>T | 3'UTR (SNP) | VAF 10/31 reads (32%) | called by muse, mutect2, varscan2
- SPEG | c.389-3075A>C | Intron (SNP) | VAF 7/95 reads (7%) | called by muse, mutect2
- TMEM86A | c.*1161G>T | 3'UTR (SNP) | VAF 32/67 reads (48%) | called by muse, mutect2, varscan2
- TRIB2 | c.-278G>C | 5'UTR (SNP) | VAF 74/246 reads (30%) | called by muse, mutect2, varscan2
- TSPEAR | c.1150-45A>T | Intron (SNP) | VAF 54/144 reads (38%) | called by muse, mutect2, varscan2
- UBP1 | chr3:33388872 G>A | 3'Flank (SNP) | VAF 33/86 reads (38%) | called by muse, mutect2, varscan2
- VWC2L | c.-53G>C | 5'UTR (SNP) | VAF 41/114 reads (36%) | catalogued as COSV100435473; called by muse, mutect2, varscan2
- ZIC1 | c.*2133A>G | 3'UTR (SNP) | VAF 19/73 reads (26%) | called by muse, mutect2, varscan2
